Somatic mutation profile of tumor specimen 0DRB5P from CCDI case PBCGAV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.8 years (1,033 days).
Specimen 0DRB5P: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a82cb636-ee19-489e-95b7-5b3e352b7469.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRB5W (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fed5a012-12da-429c-b394-6002539c3b10

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C1QA | c.551G>C p.R184P | Missense Mutation (SNP) | VAF 272/603 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.106); catalogued as COSV65890011; called by muse, mutect2, varscan2
- KSR2 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 194/437 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs373055394; called by muse, mutect2, varscan2
- MATR3 | c.1779-1G>T p.X593_splice | Splice Site (SNP) | VAF 208/434 reads (48%) | catalogued as COSV100735343, COSV63080772; called by mutect2, varscan2
- RAB5IF | c.311C>T p.T104M | Missense Mutation (SNP) | VAF 22/466 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.775); catalogued as rs757230747, COSV53410967; called by muse, mutect2
- SH3BP2 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 124/441 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.951); catalogued as rs946632787, COSV100696988; called by muse, mutect2, varscan2
- SNCAIP | c.755A>G p.E252G | Missense Mutation (SNP) | VAF 202/758 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
